Somatic mutation profile of tumor specimen TCGA-64-1680-01A (aliquot TCGA-64-1680-01A-02D-0969-08) from TCGA case TCGA-64-1680, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.7 years (23,267 days).
Specimen TCGA-64-1680-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95e69daf-2637-4494-a39e-a554a51aba69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-1680-10A (Blood Derived Normal), aliquot TCGA-64-1680-10A-01D-1040-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf79a7ae-62aa-495c-8b2d-befd3b88cd20

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 12, Nonsense Mutation 4, Intron 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM21 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50799211; called by muse, mutect2
- ADGRB2 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.523); catalogued as rs756718959, COSV57075488; called by muse, mutect2, varscan2
- ARHGEF2 | c.923G>T p.G308V (on ENST00000361247 / NM_001162383.2; = p.G280V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV58117789; called by muse, mutect2, varscan2
- ATP2B2 | c.1828C>T p.R610C (on ENST00000352432; = p.R576C on NM_001683.5) | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757018981, COSV100659980, COSV59498430; called by muse, mutect2, varscan2
- BDP1 | c.6201A>C p.R2067S | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV62435287; called by muse, mutect2, varscan2
- CCT4 | c.734A>C p.K245T | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV66702193; called by muse, mutect2, varscan2
- CDK12 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.945); catalogued as rs759485356, COSV70999458, COSV71000630; called by muse, mutect2
- CFAP61 | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs765880107, COSV55649261; called by muse, mutect2, varscan2
- FAM47C | c.2212C>G p.L738V | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.801); catalogued as COSV100792465, COSV63730867; called by muse, mutect2
- FBXO30 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52792614; called by muse, mutect2, varscan2
- GATA3 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV60522889; called by muse, mutect2, varscan2
- GGT1 | c.241C>G p.H81D | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs756699419, COSV50646074; called by muse, mutect2
- GRIN2A | c.3373G>T p.E1125* | Nonsense Mutation (SNP) | VAF 40/440 reads (9%) | catalogued as rs1200593226, COSV58026502, COSV58058380; called by muse, mutect2
- HEY1 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 10/164 reads (6%) | catalogued as COSV61233797, COSV61233992; called by muse, mutect2
- HTR1B | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64052017; called by muse, mutect2, varscan2
- ITGA8 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65224832; called by muse, mutect2, varscan2
- LCOR | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs373519273, COSV53716416; called by muse, mutect2
- LMAN1L | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs1054146436, COSV100547571, COSV59000970; called by muse, mutect2, varscan2
- MTMR4 | c.2394G>T p.M798I | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV60204369; called by muse, mutect2, varscan2
- MTTP | c.1943T>C p.L648P | Missense Mutation (SNP) | VAF 108/301 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV55510365; called by muse, mutect2, varscan2
- MYL2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.602); catalogued as COSV57408100; called by muse, mutect2
- NAIF1 | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.981); catalogued as COSV66091564, COSV66092635; called by muse, mutect2, varscan2
- OR1M1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 73/413 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs144608760; called by muse, mutect2, varscan2
- OR51B5 | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56177473; called by muse, mutect2, varscan2
- PCDHGA11 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 70/447 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV54043945; called by muse, mutect2, varscan2
- PDS5B | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59735339; called by muse, mutect2
- PIK3C2B | c.3179A>G p.N1060S | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1173631763, COSV65814551; called by muse, mutect2, varscan2
- PPP1R10 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV64740609; called by muse, mutect2
- RHBDL1 | c.464A>G p.D155G (on ENST00000219551 / NM_001318733.2; = p.D90G on NM_001278720.2) | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV53487180; called by muse, mutect2, varscan2
- RUSF1 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV57894903; called by muse, mutect2
- SCRN1 | c.22T>C p.Y8H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.492); catalogued as COSV54134613; called by muse, mutect2, varscan2
- SCTR | c.891C>G p.I297M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1177119970, COSV50032830; called by muse, mutect2
- SEC61A1 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 62/283 reads (22%) | catalogued as COSV54579274; called by muse, mutect2, varscan2
- SF1 | c.1350C>A p.Y450* | Nonsense Mutation (SNP) | VAF 36/186 reads (19%) | catalogued as COSV57117859; called by muse, mutect2, varscan2
- SNAP91 | c.2510G>C p.G837A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV52135819, COSV99535106; called by muse, mutect2
- SPO11 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs141106732; called by muse, mutect2
- STAG3 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs149765159; called by muse, mutect2, varscan2
- TLR4 | c.904G>C p.D302H (on ENST00000355622 / NM_138554.5; = p.D262H on NM_003266.4) | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV62924410; called by muse, mutect2
- UHRF1BP1L | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs766723484, COSV54437555; called by muse, mutect2, varscan2
- USP49 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs548556992, COSV51897822; called by muse, mutect2, varscan2
- DMBT1 | c.7173_7175del p.S2393del (on ENST00000338354 / NM_001377530.1; = p.S1636del on NM_004406.3) | In Frame Del (DEL) | VAF 47/182 reads (26%) | called by mutect2, pindel, varscan2
- KDM7A | c.2525del p.S842Ifs*23 | Frame Shift Del (DEL) | VAF 33/108 reads (31%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.9156C>T p.P3052= | Silent (SNP) | VAF 32/255 reads (13%) | catalogued as rs754270776, COSV60932527; called by muse, mutect2, varscan2
- ANKMY1 | c.1884C>T p.D628= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV56041825; called by muse, mutect2, varscan2
- COG5 | c.684C>T p.V228= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs773862978, COSV51765835; called by muse, mutect2, varscan2
- CUL9 | c.6102C>T p.G2034= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as rs376792971; called by muse, mutect2, varscan2
- DNAH7 | c.10335A>T p.L3445= | Silent (SNP) | VAF 66/333 reads (20%) | catalogued as COSV56789261; called by muse, mutect2, varscan2
- LCA5L | c.1527C>A p.G509= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV55747554; called by muse, mutect2, varscan2
- MAN2A2 | c.774C>G p.S258= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as COSV64640111; called by muse, varscan2
- NPAP1 | c.1665C>T p.S555= | Silent (SNP) | VAF 14/302 reads (5%) | catalogued as COSV61507317; called by muse, mutect2
- SLC39A4 | c.813G>A p.L271= (on ENST00000301305 / NM_001374839.1; = p.L246= on NM_017767.3) | Silent (SNP) | VAF 48/286 reads (17%) | catalogued as rs1363691510, COSV52781705; called by muse, mutect2, varscan2
- TACR3 | c.255C>T p.I85= | Silent (SNP) | VAF 16/224 reads (7%) | catalogued as COSV59203863; called by muse, mutect2
- TAFA4 | c.222C>G p.V74= | Silent (SNP) | VAF 13/202 reads (6%) | catalogued as COSV55146850; called by muse, mutect2
- WWC1 | c.1686C>T p.L562= | Silent (SNP) | VAF 35/240 reads (15%) | catalogued as COSV54653807; called by muse, mutect2, varscan2
- WNT4 | c.313+2142_313+2143insTG | Intron (INS) | VAF 10/36 reads (28%) | called by mutect2, varscan2
